Somatic mutation profile of tumor specimen TCGA-85-A4CN-01A (aliquot TCGA-85-A4CN-01A-11D-A24D-08) from TCGA case TCGA-85-A4CN, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.1 years (20,490 days).
Specimen TCGA-85-A4CN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f458106b-586b-4f34-9c57-8cb93c0e1c3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A4CN-10A (Blood Derived Normal), aliquot TCGA-85-A4CN-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c00bbee6-d1b8-4cee-9bdc-5bf8cbdd744b

The open-access MAF lists 198 somatic variants for this specimen: 142 protein-altering or splice-affecting, 49 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 49, Nonsense Mutation 8, Splice Site 7, Frame Shift Del 3, Intron 3, RNA 3, In Frame Ins 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AARS2 | c.1538G>A p.S513N | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99771392; called by muse, mutect2
- ABCB1 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99712798; called by muse, mutect2, varscan2
- AC008397.2 | c.317T>A p.I106N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV99441560; called by muse, mutect2, varscan2
- ACSBG1 | c.1036del p.A346Pfs*11 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as COSV51903249; called by pindel, varscan2
- ADGRE2 | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV100215933; called by muse, mutect2, varscan2
- ADGRG4 | c.5177T>A p.L1726Q | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.75); catalogued as COSV99795249; called by muse, mutect2, varscan2
- ADGRV1 | c.13742A>G p.Y4581C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.237); catalogued as rs776678308, COSV101315785; called by muse, mutect2, varscan2
- APOB | c.1715C>A p.A572E | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as rs1018158968, COSV99265140; called by muse, mutect2, varscan2
- ARHGAP17 | c.239A>G p.E80G | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99253293; called by muse, mutect2, varscan2
- ATG4A | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100619684; called by muse, mutect2
- ATP10A | c.2987A>G p.K996R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV63516817; called by muse, mutect2, varscan2
- ATP13A2 | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV100454092; called by muse, mutect2, varscan2
- BAIAP2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100347952; called by muse, mutect2, varscan2
- BCOR | c.2740T>A p.F914I | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV100653170; called by muse, mutect2
- BEND3 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs782522231, COSV100944590, COSV100944620; called by muse, mutect2, varscan2
- BIRC3 | c.900G>C p.R300S | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99679851; called by muse, mutect2, varscan2
- BMP15 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as COSV99399341; called by muse, mutect2, varscan2
- BMP15 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV53141636, COSV99399345; called by muse, mutect2, varscan2
- BPTF | c.2323C>G p.R775G | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1364777438, COSV100074678, COSV100074734; called by muse, mutect2, varscan2
- C6 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99666937; called by muse, mutect2, varscan2
- C8A | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100776480; called by muse, mutect2, varscan2
- CACNA2D2 | c.1874A>G p.Y625C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780181502, COSV99817446; called by muse, mutect2, varscan2
- CAD | c.4213C>T p.L1405F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.848); catalogued as COSV99254914; called by mutect2, varscan2
- CALCR | c.1300G>T p.G434W (on ENST00000649521 / NM_001164737.2; = p.G418W on NM_001742.4) | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100810396, COSV100810660; called by muse, mutect2, varscan2
- CASP4 | c.602A>T p.D201V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101274139; called by muse, mutect2, varscan2
- CATSPERB | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV56429523; called by muse, mutect2, varscan2
- CEMIP2 | c.772A>G p.T258A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1305548428, COSV100987342; called by muse, mutect2, varscan2
- CFAP251 | c.18A>T p.E6D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.482); catalogued as COSV99945635; called by muse, mutect2, varscan2
- CFAP52 | c.1349C>T p.T450I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs916341979, COSV100235076; called by muse, mutect2, varscan2
- CGNL1 | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV99848069; called by muse, mutect2, varscan2
- CNTNAP5 | c.3749T>A p.I1250N | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV101443409; called by muse, mutect2, varscan2
- COL12A1 | c.1289-2A>T p.X430_splice | Splice Site (SNP) | VAF 23/126 reads (18%) | catalogued as COSV100485853; called by muse, mutect2, varscan2
- COL21A1 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99778431; called by muse, mutect2
- COL5A2 | c.2456G>C p.G819A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880196; called by muse, mutect2, varscan2
- CSMD3 | c.2125C>A p.Q709K (on ENST00000297405 / NM_001363185.1; = p.Q605K on NM_052900.3) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV52147246, COSV99831996; called by muse, mutect2, varscan2
- CST8 | c.132C>A p.N44K | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV99849961; called by muse, mutect2, varscan2
- CTAG2 | c.341C>A p.A114E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.556); catalogued as COSV99908916; called by muse, mutect2, varscan2
- CUL3 | c.2030-1G>A p.X677_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100024155; called by muse, mutect2, varscan2
- CX3CR1 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV100843177; called by muse, mutect2, varscan2
- CXorf56 | c.167C>A p.S56Y | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100233371; called by muse, mutect2, varscan2
- CYP3A5 | c.1321T>A p.C441S | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99769702; called by muse, mutect2, varscan2
- DCSTAMP | c.294G>T p.L98F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52578892; called by muse, mutect2, varscan2
- DNAJB9 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99974456; called by muse, mutect2
- DSCAML1 | c.4804C>T p.R1602* (on ENST00000321322; = p.R1542* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100355644; called by muse, mutect2, varscan2
- DTX4 | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99915279; called by muse, mutect2, varscan2
- DYSF | c.3208G>T p.E1070* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as COSV50617327, COSV99246244; called by muse, mutect2, varscan2
- ECSIT | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99368988; called by muse, mutect2, varscan2
- ERC1 | c.2555T>G p.I852R (on ENST00000360905 / NM_178040.4; = p.I824R on NM_178039.4) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100705912; called by muse, mutect2, varscan2
- FEZF1 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs1336656398, COSV100484481, COSV58658657; called by muse, mutect2, varscan2
- FRMD5 | c.329+2T>A p.X110_splice | Splice Site (SNP) | VAF 52/220 reads (24%) | catalogued as COSV101296421; called by muse, mutect2, varscan2
- FRMPD4 | c.3751G>A p.A1251T | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs758946317, COSV66214027; called by muse, mutect2, varscan2
- GABRB3 | c.1078C>A p.R360= | Splice Region (SNP) | VAF 70/177 reads (40%) | catalogued as COSV100159362, COSV100160423; called by muse, mutect2, varscan2
- GFOD1 | c.781G>C p.V261L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV101015037, COSV64955293; called by muse, mutect2, varscan2
- GJA5 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 37/84 reads (44%) | catalogued as COSV99605457; called by muse, mutect2, varscan2
- GP6 | c.903G>T p.R301S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV100117479; called by muse, mutect2
- GRIK4 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV101483580; called by muse, mutect2, varscan2
- HDAC4 | c.3119G>A p.R1040H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs776314282, COSV61861497; called by muse, mutect2, varscan2
- IDH3G | c.461T>G p.V154G | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99473113; called by muse, mutect2, varscan2
- IL6 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs752257060, COSV99331427, COSV99331635; called by muse, mutect2, varscan2
- IMPG2 | c.1657G>T p.V553L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99515358; called by muse, mutect2, varscan2
- ITPRID1 | c.1753G>C p.G585R | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as COSV100086234, COSV100087273; called by muse, mutect2, varscan2
- KANK2 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV100763163, COSV62006498; called by muse, mutect2, varscan2
- KCNH7 | c.1316A>G p.Q439R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100035435; called by muse, mutect2, varscan2
- KCNK13 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as rs369202821, COSV56418467; called by muse, mutect2, varscan2
- KCNQ3 | c.2278T>G p.C760G | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101195926; called by muse, mutect2, varscan2
- KIF4B | c.2791G>A p.V931M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs776512527, COSV101469256, COSV70532499; called by muse, mutect2, varscan2
- KLRC1 | c.409A>G p.R137G | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.562); catalogued as rs1450640347, COSV100760793; called by muse, mutect2, varscan2
- L1CAM | c.3508G>T p.D1170Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100649058; called by muse, mutect2
- LGI1 | c.1633A>T p.T545S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV101004398; called by muse, mutect2, varscan2
- LRP1 | c.7804+2T>G p.X2602_splice | Splice Site (SNP) | VAF 3/41 reads (7%) | catalogued as COSV99675537; called by muse, mutect2
- LRP1B | c.5528G>A p.G1843D | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101255667, COSV67255734; called by muse, mutect2
- LRRK2 | c.6479A>T p.H2160L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100109918; called by muse, mutect2, varscan2
- MAGEC3 | c.1494C>A p.F498L | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.414); catalogued as COSV53575710, COSV53577836; called by muse, mutect2, varscan2
- MAMLD1 | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); catalogued as COSV99475847; called by muse, mutect2, varscan2
- MGST1 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1449086441, COSV99163164; called by muse, mutect2, varscan2
- MIB1 | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99838664; called by muse, mutect2, varscan2
- MLLT10 | c.1052-2A>T p.X351_splice | Splice Site (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100307957; called by mutect2, varscan2
- MMUT | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV99222301; called by muse, mutect2, varscan2
- MOXD1 | c.1480G>T p.G494W | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100381459; called by muse, mutect2
- MROH2B | c.3241C>T p.H1081Y | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV68182210; called by muse, mutect2
- MTHFD2 | c.181G>T p.V61L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV99902985; called by muse, mutect2, varscan2
- MXRA5 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV54241363; called by muse, mutect2, varscan2
- MYO15A | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); catalogued as rs373606351, COSV99234650; called by muse, mutect2, varscan2
- MYO7B | c.4771C>T p.Q1591* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101268094; called by muse, mutect2
- NDUFAB1 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1567410714, COSV99141459; called by muse, mutect2
- NF1 | c.5313A>T p.K1771N (on ENST00000358273 / NM_001042492.3; = p.K1750N on NM_000267.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV100646728; called by muse, mutect2, varscan2
- OR2L8 | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.424); catalogued as rs1050040628, COSV100594154; called by muse, mutect2, varscan2
- OR51A2 | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100985047, COSV66748664; called by muse, mutect2, varscan2
- OR5D18 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV61738934; called by muse, mutect2, varscan2
- OTOF | c.416T>C p.L139P | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.193); catalogued as COSV99717373; called by muse, mutect2, varscan2
- PGRMC1 | c.169A>T p.S57C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99483530; called by muse, mutect2, varscan2
- PHIP | c.2459A>T p.D820V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV99243884; called by muse, mutect2, varscan2
- PKN2 | c.995A>T p.E332V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100281496; called by muse, mutect2, varscan2
- PLK4 | c.908G>T p.S303I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV99584602; called by muse, mutect2, varscan2
- PLPPR4 | c.643T>A p.Y215N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100926768; called by muse, mutect2, varscan2
- PPEF1 | c.1870G>T p.G624* | Nonsense Mutation (SNP) | VAF 4/82 reads (5%) | catalogued as COSV100583689; called by muse, mutect2
- PPEF1 | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100583690; called by muse, mutect2
- PRRC2A | c.6470del p.R2157Pfs*56 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as COSV52988660; called by mutect2, varscan2
- PSME4 | c.2966C>A p.T989K | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV66365237; called by muse, mutect2, varscan2
- RARB | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.175); catalogued as rs1320464729; called by muse, mutect2, varscan2
- RNFT2 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.754); catalogued as rs774196399, COSV99985016, COSV99985191; called by muse, mutect2, varscan2
- RTN4 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100463036; called by muse, mutect2, varscan2
- RYR3 | c.7529A>G p.Y2510C (on ENST00000389232; = p.Y2511C on NM_001036.6) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1437149667, COSV101212555; called by muse, mutect2
- RYR3 | c.11745C>A p.F3915L (on ENST00000389232; = p.F3916L on NM_001036.6) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775956290, COSV101212557, COSV66790442; called by muse, mutect2, varscan2
- SCN10A | c.843G>T p.M281I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV101479364; called by muse, mutect2, varscan2
- SCN11A | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM166897, COSV100181407, COSV56581345; called by muse, mutect2, varscan2
- SCN1A | c.2125C>A p.Q709K (on ENST00000303395 / NM_001202435.3; = p.Q698K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.065); catalogued as COSV57671652; called by muse, mutect2, varscan2
- SH2B1 | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV59465608; called by muse, mutect2, varscan2
- SHPRH | c.8G>C p.S3T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV99261933; called by muse, mutect2, varscan2
- SLC16A13 | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100338608; called by muse, mutect2
- SLC27A6 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs779815009, COSV99322584; called by muse, varscan2
- STK26 | c.784-1G>T p.X262_splice | Splice Site (SNP) | VAF 6/77 reads (8%) | catalogued as COSV100688669; called by muse, mutect2
- SULT2A1 | c.460T>C p.C154R | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV99705400; called by muse, mutect2, varscan2
- TBC1D8B | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99344227; called by muse, mutect2
- TDRD7 | c.373C>A p.Q125K | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100795565; called by muse, mutect2, varscan2
- TEX13B | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.702); catalogued as COSV100258357; called by muse, mutect2, varscan2
- THOC2 | c.2293C>A p.L765I | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99833140; called by muse, mutect2, varscan2
- TIE1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs141628049; called by muse, mutect2, varscan2
- TIGD4 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100427938; called by muse, mutect2, varscan2
- TLE2 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.097); catalogued as COSV99504242; called by muse, mutect2, varscan2
- TLE2 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.296); catalogued as COSV99504246; called by muse, mutect2, varscan2
- TMEM266 | c.642G>T p.R214S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101189602; called by muse, mutect2, varscan2
- TRIM37 | c.1666A>G p.M556V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as rs1249614655, COSV99232775; called by muse, mutect2
- VPS13A | c.8803A>G p.M2935V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs772029827, COSV100652571; called by muse, mutect2, varscan2
- VPS13C | c.1023G>T p.M341I (on ENST00000644861 / NM_020821.3; = p.M298I on NM_017684.5) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as COSV99828212; called by muse, mutect2
- XDH | c.2311A>G p.M771V | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1238629398, COSV101052176; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2426C>A p.T809N | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99648459; called by muse, mutect2, varscan2
- ZNF25 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100224588; called by muse, mutect2
- ZNF266 | c.29C>A p.T10K | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV100749374; called by muse, mutect2
- ZNF285 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 38/141 reads (27%) | catalogued as COSV100449966; called by muse, mutect2, varscan2
- ZNF480 | c.328+2T>C p.X110_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV57994682; called by muse, mutect2
- ZNF492 | c.1369G>C p.A457P | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV101513989; called by muse, mutect2, varscan2
- ZNF804A | c.2758G>T p.V920L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV100167434; called by muse, mutect2, varscan2
- ZNF836 | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.885); catalogued as COSV100440850; called by muse, mutect2, varscan2
- ACSBG1 | c.1030T>A p.W344R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, varscan2
- ASPM | c.253del p.A85Rfs*34 | Frame Shift Del (DEL) | VAF 50/146 reads (34%) | called by mutect2, pindel*, varscan2
- FAM153B | c.1074A>T p.K358N (on ENST00000253490; = p.K281N on NM_001265615.1) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); called by mutect2, varscan2
- FCGBP | c.9187C>G p.P3063A | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- GTF2I | c.586+1_586+3dup | In Frame Ins (INS) | VAF 59/194 reads (30%) | called by mutect2, pindel, varscan2
- IGKV6D-41 | c.248G>T p.S83I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TRBV2 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ADCY8 | c.3735C>T p.T1245= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs370637636; called by muse, mutect2, varscan2
- ADGRG3 | c.1221C>T p.T407= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1156896428, COSV100342275; called by muse, mutect2, varscan2
- ARID3A | c.1728G>T p.G576= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV99708350; called by muse, varscan2
- ATRX | c.5496A>G p.E1832= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100970574; called by muse, mutect2, varscan2
- BAALC | c.393C>T p.G131= (on ENST00000297574 / NM_001364874.1; = p.G96= on NM_024812.3) | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV99883412; called by muse, mutect2
- CHD1 | c.2388A>G p.L796= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs752845055, COSV99399369; called by muse, mutect2, varscan2
- CNTNAP2 | c.3456C>G p.L1152= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV100665506, COSV100665654; called by muse, mutect2, varscan2
- COL23A1 | c.918A>C p.T306= | Silent (SNP) | VAF 44/158 reads (28%) | catalogued as COSV101178565; called by muse, mutect2, varscan2
- COL4A2 | c.789G>T p.A263= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100847318, COSV64624722; called by muse, mutect2, varscan2
- CPT1A | c.1698A>G p.P566= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99681044; called by muse, mutect2, varscan2
- DIO1 | c.453C>A p.V151= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100498892; called by muse, mutect2, varscan2
- DNAJC6 | c.204T>C p.Y68= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as rs770837044, COSV99674621; called by muse, mutect2, varscan2
- FGD3 | c.1545G>A p.S515= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs745672682, COSV100490514; called by muse, mutect2, varscan2
- FGD5 | c.1212G>T p.A404= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99547879; called by muse, mutect2, varscan2
- FGF10 | c.489C>A p.T163= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs755749426, COSV99240064, COSV99240450; called by muse, mutect2, varscan2
- FPGS | c.873G>T p.P291= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100948805, COSV64675741; called by muse, varscan2
- JDP2 | c.276G>A p.K92= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99966644; called by muse, mutect2
- MAGEC2 | c.582C>A p.G194= | Silent (SNP) | VAF 16/172 reads (9%) | catalogued as COSV55998146, COSV99909548; called by muse, mutect2
- MAPKBP1 | c.1563C>T p.D521= (on ENST00000456763 / NM_001128608.2; = p.D515= on NM_014994.3) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99529281; called by muse, mutect2, varscan2
- MSH3 | c.3336G>T p.T1112= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs772361271, COSV99433302; called by muse, mutect2, varscan2
- NID1 | c.834C>T p.D278= | Silent (SNP) | VAF 141/281 reads (50%) | catalogued as rs371831151; called by muse, mutect2, varscan2
- NIPSNAP3A | c.741A>G p.K247= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs781758865, COSV66106990; called by muse, mutect2, varscan2
- NKX2-5 | c.858C>T p.A286= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs775959611, COSV100234795; called by muse, varscan2
- OR2C3 | c.657C>T p.Y219= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs762023698, COSV63574904; called by muse, mutect2, varscan2
- OR6C6 | c.501T>C p.C167= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100626454; called by muse, mutect2, varscan2
- OR6K3 | c.601C>T p.L201= (on ENST00000368146; = p.L185= on NM_001005327.2) | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as COSV100933850; called by muse, mutect2, varscan2
- PCDHA8 | c.1689G>A p.P563= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV65327882; called by muse, mutect2, varscan2
- PLA2G1B | c.369C>T p.N123= | Silent (SNP) | VAF 52/240 reads (22%) | catalogued as rs199972494, COSV100387519, COSV57679230; called by muse, mutect2, varscan2
- PPP1R3A | c.510T>C p.Y170= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99492651; called by muse, mutect2, varscan2
- RALBP1 | c.49A>C p.R17= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99191913; called by muse, mutect2, varscan2
- RRM2B | c.669C>A p.L223= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV52568591, COSV99310368; called by muse, mutect2, varscan2
- SERPINI1 | c.441G>T p.V147= | Silent (SNP) | VAF 59/88 reads (67%) | catalogued as COSV99855020; called by muse, mutect2, varscan2
- SLC16A13 | c.564C>T p.L188= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV100338609; called by muse, mutect2
- SLC16A13 | c.672C>A p.T224= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs1274698167, COSV100338610; called by muse, mutect2
- SLC9C1 | c.1314G>A p.S438= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs774351782, COSV59887410; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.867A>G p.K289= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99833351; called by muse, mutect2, varscan2
- TEK | c.1899C>A p.T633= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV101193360; called by muse, mutect2, varscan2
- TEX13A | c.678C>A p.P226= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100781181; called by mutect2, varscan2
- TIMP2 | c.315A>C p.G105= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV99430344; called by muse, mutect2, varscan2
- TMC5 | c.1057T>C p.L353= (on ENST00000396229 / NM_001105248.1; = p.L107= on NM_024780.5) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99572383; called by muse, mutect2, varscan2
- TRPC4 | c.1179C>T p.N393= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100156592; called by muse, mutect2, varscan2
- TTC39B | c.315T>C p.F105= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99894865; called by muse, mutect2
- TTF1 | c.1752G>A p.R584= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100524654; called by muse, mutect2, varscan2
- UNC80 | c.513G>A p.E171= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV99779251; called by muse, mutect2, varscan2
- VAMP2 | c.132C>T p.D44= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100336088; called by muse, mutect2, varscan2
- YIF1B | c.201G>T p.T67= (on ENST00000339413 / NM_001039673.3; = p.T52= on NM_001039671.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100007890; called by muse, varscan2
- ZC3H18 | c.2205G>A p.L735= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- ZNF25 | c.213A>T p.V71= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100224587, COSV56922908; called by muse, mutect2
- ZNF677 | c.450T>C p.S150= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100447874; called by muse, mutect2, varscan2
- CABYR | c.*17-456G>A | Intron (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100111544; called by muse, mutect2
- CCSER1 | c.2094+23147G>A | Intron (SNP) | VAF 13/118 reads (11%) | catalogued as rs200975463, COSV61419001; called by muse, varscan2
- DMRT2 | c.629-444T>C | Intron (SNP) | VAF 20/49 reads (41%) | catalogued as rs1442294841, COSV99426033; called by muse, mutect2, varscan2
- KIR3DX1 | n.408C>A | RNA (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99683254; called by muse, mutect2, varscan2
- MIR513B | n.50A>T | RNA (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- MIR542 | n.8C>A | RNA (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827989 T>A | 3'Flank (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100157635; called by muse, mutect2
